Somatic mutation profile of tumor specimen TCGA-GV-A3QI-01A (aliquot TCGA-GV-A3QI-01A-11D-A21Z-08) from TCGA case TCGA-GV-A3QI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 47.6 years (17,383 days).
Specimen TCGA-GV-A3QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2810a4eb-6383-41f0-a225-d12657e5cc32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3QI-10A (Blood Derived Normal), aliquot TCGA-GV-A3QI-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31b7b1b2-49d3-4b8c-b22b-ed6e996cfd81

The open-access MAF lists 507 somatic variants for this specimen: 364 protein-altering or splice-affecting, 130 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 130, Nonsense Mutation 22, Frame Shift Del 11, Splice Site 11, Intron 6, 5'Flank 2, 3'UTR 2, 5'UTR 2, In Frame Del 2, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.3427G>A p.E1143K (on ENST00000404938 / NM_001163941.2; = p.E698K on NM_178559.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51709161; called by muse, mutect2, varscan2
- ABI1 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.34); catalogued as rs777010816, COSV61016833; called by muse, mutect2, varscan2
- ABTB2 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54387960; called by muse, mutect2, varscan2
- ACD | c.748G>A p.A250T (on ENST00000620338; = p.A161T on NM_022914.3) | Missense Mutation (SNP) | VAF 90/95 reads (95%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV54667525; called by muse, mutect2, varscan2
- ACIN1 | c.3917G>A p.R1306K | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.444); catalogued as rs925515073, COSV52975971; called by muse, varscan2
- ACVRL1 | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66360159; called by muse, mutect2, varscan2
- ADAM15 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs759981258, COSV55126746; called by muse, mutect2, varscan2
- ADAM23 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52213597, COSV52214832, COSV52220227; called by muse, mutect2, varscan2
- ADAMTSL3 | c.5010A>T p.K1670N | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54446934; called by muse, mutect2
- ADGRG1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV65635605; called by muse, mutect2, varscan2
- ADGRL1 | c.3349T>A p.C1117S (on ENST00000340736 / NM_001008701.3; = p.C1112S on NM_014921.5) | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61564637; called by muse, mutect2, varscan2
- ADGRV1 | c.14791G>C p.E4931Q | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV67984760; called by muse, mutect2, varscan2
- ADGRV1 | c.15740G>A p.R5247K | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs751832113, COSV67984764; called by muse, mutect2, varscan2
- AHCYL2 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61486951; called by muse, mutect2, varscan2
- AHNAK2 | c.11300C>T p.P3767L | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV60914868; called by muse, mutect2, varscan2
- ALOX15 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as COSV99541721; called by muse, mutect2, varscan2
- ALX1 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV57492190; called by muse, mutect2, varscan2
- ANK1 | c.5314C>A p.Q1772K | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as CM156164, COSV55880982; called by muse, mutect2, varscan2
- ANK2 | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV52160087; called by muse, mutect2, varscan2
- ANKRD50 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV72385523; called by muse, mutect2, varscan2
- AP1B1 | c.14A>C p.K5T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58017379; called by muse, mutect2, varscan2
- ARAP3 | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53350551, COSV99499187; called by muse, mutect2, varscan2
- AREL1 | c.1079A>T p.K360M | Missense Mutation (SNP) | VAF 454/718 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62666384; called by muse, mutect2, varscan2
- ARHGAP12 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60963076; called by muse, mutect2, varscan2
- ARHGEF18 | c.1160A>T p.Q387L (on ENST00000359920 / NM_001130955.2; = p.Q283L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV60469602; called by muse, mutect2, varscan2
- ARMC5 | c.1742A>C p.E581A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51656291; called by muse, mutect2, varscan2
- ATP2A1 | c.1804C>A p.P602T | Missense Mutation (SNP) | VAF 96/160 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62869413; called by muse, varscan2
- ATP2A1 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs758544349, COSV62869416; called by muse, varscan2
- ATP2B1 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 61/230 reads (27%) | catalogued as COSV53805728; called by muse, mutect2, varscan2
- ATP2C1 | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV60756018; called by muse, mutect2, varscan2
- ATP5F1B | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs747376704, COSV51636439; called by muse, mutect2, varscan2
- ATP6V0A1 | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV52873179; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV52269357; called by muse, mutect2, varscan2
- B4GALNT3 | c.1715A>T p.Q572L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV56752208; called by muse, mutect2, varscan2
- BAZ2B | c.3052A>G p.M1018V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1337695661, COSV54275535; called by muse, varscan2
- BSN | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56517477; called by muse, mutect2, varscan2
- BUB1 | c.905A>C p.Q302P | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV57063414; called by muse, mutect2, varscan2
- BUD13 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV52768166; called by muse, mutect2, varscan2
- C12orf4 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54206886; called by muse, mutect2, varscan2
- C9 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV54676634; called by muse, mutect2, varscan2
- CABS1 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV56733489; called by muse, mutect2, varscan2
- CAD | c.1711A>G p.R571G | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53026645; called by muse, mutect2, varscan2
- CADPS2 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV57362339; called by muse, mutect2, varscan2
- CAPN5 | c.881A>G p.Y294C (on ENST00000456580; = p.Y254C on NM_004055.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53687692; called by muse, mutect2, varscan2
- CASK | c.1493A>G p.D498G | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1409442804, COSV59366197; called by muse, mutect2, varscan2
- CD207 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs782521829, COSV69652041; called by muse, mutect2, varscan2
- CD247 | c.53T>A p.I18N | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV62978087; called by muse, varscan2
- CD40 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 77/105 reads (73%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs371997367; called by muse, mutect2, varscan2
- CELSR3 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs771585065, COSV50857484; called by muse, mutect2, varscan2
- CENPQ | c.387A>T p.K129N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV59921132; called by muse, mutect2, varscan2
- CEP112 | c.2237A>C p.Q746P | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV67139153; called by muse, mutect2, varscan2
- CEP290 | c.3978G>T p.K1326N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as COSV58351590; called by muse, mutect2, varscan2
- CER1 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.123); catalogued as COSV66603177; called by muse, mutect2, varscan2
- CFAP100 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 43/90 reads (48%) | catalogued as rs1335051830; called by muse, mutect2, varscan2
- CFAP100 | c.1699_1700del p.A567Pfs*3 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs765899095; called by pindel, varscan2
- CHD3 | c.1716C>G p.I572M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV57874856; called by muse, mutect2, varscan2
- CHRAC1 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143839289; called by muse, mutect2, varscan2
- CHRM3 | c.1520A>T p.Y507F | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55088392; called by muse, varscan2
- CKAP5 | c.2250-1G>A p.X750_splice | Splice Site (SNP) | VAF 13/23 reads (57%) | catalogued as COSV56367392, COSV56367522; called by muse, mutect2, varscan2
- CLCN4 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 238/249 reads (96%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV66466433; called by muse, mutect2, varscan2
- CLCNKA | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 75/81 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58891547; called by muse, mutect2, varscan2
- CLPX | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV55644401; called by muse, mutect2, varscan2
- COL11A2 | c.2584G>A p.G862R (on ENST00000341947 / NM_080680.3; = p.G755R on NM_080679.2) | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59496654; called by muse, mutect2, varscan2
- COL2A1 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 98/265 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61527770, COSV61530331; called by muse, mutect2, varscan2
- COL5A3 | c.3559G>A p.G1187S | Missense Mutation (SNP) | VAF 107/151 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764331999, COSV53410328; called by muse, mutect2, varscan2
- COX10 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs772223730, COSV55404903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREB3L3 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1388849390, COSV50195023; called by muse, mutect2, varscan2
- CRTC2 | c.1480G>C p.V494L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57842679; called by muse, mutect2, varscan2
- CSMD2 | c.5769G>T p.E1923D | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV53910041; called by muse, mutect2, varscan2
- CX3CL1 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50055830; called by muse, mutect2, varscan2
- CYP1A1 | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs759604228, COSV65697145; called by muse, mutect2, varscan2
- DAW1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs755454844, COSV59365245, COSV59366294; called by muse, mutect2
- DCAF6 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as COSV56578441; called by muse, mutect2, varscan2
- DKK3 | c.795C>A p.C265* | Nonsense Mutation (SNP) | VAF 27/28 reads (96%) | catalogued as rs1397152240; called by muse, mutect2, varscan2
- DKK3 | c.434A>T p.H145L | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV58868546; called by muse, mutect2, varscan2
- DMXL1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV60710902; called by muse, mutect2, varscan2
- DNAI1 | c.1716C>G p.I572M | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV54280928; called by muse, mutect2, varscan2
- DNAJC22 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV67711835; called by muse, mutect2, varscan2
- DOP1A | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.151); catalogued as COSV52709994; called by muse, mutect2, varscan2
- DOT1L | c.2406G>A p.S802= | Splice Region (SNP) | VAF 31/157 reads (20%) | catalogued as rs777914517, COSV67109628; called by muse, mutect2, varscan2
- DROSHA | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV60773524, COSV60775722; called by muse, mutect2, varscan2
- DSCAM | c.5987G>A p.R1996Q | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs759558023, COSV68026253; called by muse, mutect2, varscan2
- DSCAM | c.5222C>A p.T1741K | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV68026257; called by muse, mutect2, varscan2
- DSG1 | c.2043G>C p.M681I | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV57135161; called by muse, mutect2, varscan2
- ECE1 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313819749, COSV51664443; called by muse, mutect2, varscan2
- EFCAB6 | c.1984-1G>A p.X662_splice | Splice Site (SNP) | VAF 45/100 reads (45%) | catalogued as COSV53062794; called by muse, mutect2, varscan2
- EIF3A | c.2837G>C p.R946T | Missense Mutation (SNP) | VAF 100/104 reads (96%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64961357; called by muse, varscan2
- EML1 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV51744924; called by muse, mutect2, varscan2
- ENOX2 | c.784G>T p.D262Y (on ENST00000338144 / NM_001382520.1; = p.D233Y on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100583947, COSV57651197; called by muse, mutect2, varscan2
- ENPEP | c.1708C>G p.Q570E | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54448698, COSV54450708; called by muse, mutect2, varscan2
- EPHA6 | c.2429T>A p.F810Y (on ENST00000389672 / NM_001080448.3; = p.F202Y on NM_173655.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.981); catalogued as COSV67571172; called by muse, mutect2, varscan2
- EPHB1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as rs1164993873, COSV67660945; called by muse, mutect2, varscan2
- ERICH3 | c.2360A>T p.D787V | Missense Mutation (SNP) | VAF 70/72 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV58606129; called by muse, mutect2, varscan2
- ESRRG | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV63159841; called by muse, mutect2, varscan2
- ETV1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54142137; called by muse, mutect2, varscan2
- FAM13B | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV50366078; called by muse, mutect2, varscan2
- FAP | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51861566; called by muse, mutect2, varscan2
- FARSA | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100108664, COSV58904882; called by muse, mutect2, varscan2
- FAT3 | c.6743A>G p.Y2248C | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53107323; called by muse, mutect2, varscan2
- FBH1 | c.967G>A p.E323K (on ENST00000362091 / NM_178150.3; = p.E374K on NM_032807.4) | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765636339, COSV62982506; called by muse, mutect2, varscan2
- FBLN1 | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs1171895358, COSV59937771; called by muse, mutect2, varscan2
- FBN2 | c.3352G>T p.E1118* | Nonsense Mutation (SNP) | VAF 35/71 reads (49%) | catalogued as COSV52503780, COSV52519067; called by muse, mutect2, varscan2
- FBN3 | c.3502G>A p.V1168M | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54459954; called by muse, mutect2, varscan2
- FGR | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 47/47 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64969476; called by muse, mutect2, varscan2
- FITM2 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67679161; called by muse, mutect2, varscan2
- FLNC | c.7321G>A p.D2441N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.756); catalogued as COSV57955549; called by muse, mutect2, varscan2
- FMO2 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV52947614; called by muse, mutect2, varscan2
- FREM2 | c.4342G>C p.D1448H | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54837015; called by muse, mutect2, varscan2
- FRY | c.9007C>G p.L3003V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.163); catalogued as COSV66511173; called by muse, mutect2, varscan2
- GAK | c.2686G>T p.V896L | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58504540; called by muse, mutect2, varscan2
- GDF11 | c.876C>G p.N292K | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.062); catalogued as COSV57689687; called by muse, mutect2, varscan2
- GHRHR | c.812+1G>A p.X271_splice | Splice Site (SNP) | VAF 32/123 reads (26%) | catalogued as rs770246828, CS096025, COSV58196255; called by muse, mutect2, varscan2
- GJD2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1269006378, COSV51748108; called by muse, mutect2, varscan2
- GRM2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV56584784; called by muse, mutect2, varscan2
- GUCY1A1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56651456; called by muse, mutect2, varscan2
- HCN1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs771234977, COSV57507475, COSV57509060; called by muse, mutect2, varscan2
- HECTD4 | c.1505A>G p.N502S | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.995); catalogued as COSV66391617; called by muse, mutect2, varscan2
- HECW2 | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.011); catalogued as COSV53658627; called by muse, mutect2, varscan2
- HFM1 | c.2783T>C p.L928P | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54026678; called by muse, mutect2, varscan2
- HIP1R | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.177); catalogued as COSV53441434; called by muse, mutect2
- ICA1 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1487937381, COSV55577148, COSV55578677; called by muse, mutect2, varscan2
- IGHG1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as rs374573509; called by muse, mutect2, varscan2
- IGSF1 | c.3077C>T p.T1026I | Missense Mutation (SNP) | VAF 102/104 reads (98%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV63837342; called by muse, mutect2, varscan2
- IL12B | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV51454870; called by muse, mutect2, varscan2
- IL32 | c.55del p.V19* | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as COSV50404972; called by mutect2, pindel, varscan2
- ILDR2 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 407/750 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54830750; called by muse, mutect2, varscan2
- IPO7 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs759434449, COSV63352642; called by muse, mutect2, varscan2
- ITGB4 | c.3347T>A p.M1116K | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV52325596; called by muse, mutect2, varscan2
- ITSN2 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV61946903; called by muse, mutect2, varscan2
- KCNJ2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV54661579; called by muse, mutect2
- KCNT1 | c.2816T>A p.F939Y (on ENST00000488444; = p.F958Y on NM_020822.3) | Missense Mutation (SNP) | VAF 78/107 reads (73%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV53701100; called by muse, mutect2, varscan2
- KDM1B | c.2419A>G p.T807A (on ENST00000449850; = p.T574A on NM_153042.4) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV52810515; called by muse, mutect2
- KIAA0753 | c.2685G>A p.M895I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV63817340; called by muse, mutect2, varscan2
- KIF14 | c.3049C>A p.H1017N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV66261670; called by muse, mutect2, varscan2
- KMT2D | c.15585G>C p.Q5195H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV56420838, COSV56454982; called by muse, mutect2, varscan2
- KMT2D | c.15311G>A p.C5104Y | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56437823; called by muse, mutect2, varscan2
- KPNB1 | c.1809C>G p.I603M | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV51596869; called by muse, mutect2
- KRT222 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101229475, COSV67498220; called by muse, mutect2, varscan2
- KRT36 | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1360195097, COSV60203311; called by muse, mutect2, varscan2
- KRT85 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 131/339 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV57736807; called by muse, mutect2, varscan2
- KRTAP22-1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 138/150 reads (92%) | PolyPhen benign (0.007); catalogued as COSV58182261; called by muse, mutect2, varscan2
- KRTAP3-1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as rs778012410, COSV66957490; called by muse, mutect2, varscan2
- KRTAP8-1 | c.62A>C p.Y21S | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV61597932, COSV61598422; called by muse, mutect2, varscan2
- LDB2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58768776; called by muse, mutect2, varscan2
- LPA | c.3047G>T p.R1016L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60300269, COSV60301484, COSV60312833; called by muse, mutect2, varscan2
- LPO | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51858594, COSV51861629; called by muse, mutect2, varscan2
- LRGUK | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.335); catalogued as COSV53637618, COSV53643428; called by muse, mutect2, varscan2
- LRRC52 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV54232097; called by muse, mutect2, varscan2
- LTBP1 | c.4537A>G p.N1513D (on ENST00000404816 / NM_206943.4; = p.N1187D on NM_000627.4) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV55379030; called by muse, mutect2, varscan2
- LTBP4 | c.1676G>A p.G559E (on ENST00000308370 / NM_001042544.1; = p.G522E on NM_003573.2) | Missense Mutation (SNP) | VAF 64/66 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52581113; called by muse, mutect2, varscan2
- LZTR1 | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.622); catalogued as COSV53147334; called by muse, mutect2, varscan2
- MAGEB2 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66780669; called by muse, mutect2
- MAP2K3 | c.628G>T p.G210C (on ENST00000342679 / NM_145109.3; = p.G181C on NM_002756.4) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57567183; called by muse, mutect2, varscan2
- MAPK7 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV55190386; called by muse, mutect2, varscan2
- MAPK9 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 342/809 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV104417284, COSV58121799; called by muse, mutect2, varscan2
- MAPT | c.1543A>G p.K515E (on ENST00000262410 / NM_001377265.1; = p.K440E on NM_016835.4) | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1420374757, COSV52240218; called by muse, mutect2, varscan2
- MBP | c.713G>A p.G238E (on ENST00000355994 / NM_001025101.2; = p.G131E on NM_002385.3) | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62829213; called by muse, mutect2, varscan2
- MCM3 | c.1151C>T p.S384F (on ENST00000229854 / NM_001366374.2; = p.S374F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57717573; called by muse, varscan2
- MED15 | c.1634C>A p.P545H (on ENST00000263205 / NM_001003891.3; = p.P505H on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53029119; called by muse, mutect2, varscan2
- MFAP5 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63945341; called by muse, mutect2, varscan2
- MICAL2 | c.1830G>A p.M610I | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2, varscan2
- MINDY3 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53220198; called by muse, mutect2, varscan2
- MPDZ | c.6079G>A p.E2027K (on ENST00000319217 / NM_001330637.2; = p.E1998K on NM_003829.5) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV59917716; called by muse, mutect2, varscan2
- MRC1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100509578; called by muse, mutect2, varscan2
- MRC2 | c.2162A>T p.H721L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.829); catalogued as COSV57636141, COSV57639555; called by muse, mutect2, varscan2
- MRPS18C | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55029612; called by mutect2, varscan2
- MTCH1 | c.1068G>C p.W356C (on ENST00000373627 / NM_001271641.1; = p.W339C on NM_014341.2) | Missense Mutation (SNP) | VAF 67/72 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV65320501, COSV65320671; called by muse, mutect2, varscan2
- MTHFD1 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278928695, COSV53700219; called by muse, mutect2, varscan2
- MTR | c.1816G>A p.G606S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV63964809; called by muse, mutect2, varscan2
- MUC16 | c.43060G>C p.E14354Q | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.828); catalogued as COSV66690795; called by muse, mutect2, varscan2
- MUC16 | c.21955G>C p.A7319P | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV67464207; called by muse, mutect2, varscan2
- MUC17 | c.9793A>G p.T3265A | Missense Mutation (SNP) | VAF 632/815 reads (78%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV60287872; called by muse, mutect2, varscan2
- MYO9B | c.4639A>T p.I1547F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV68278946; called by muse, mutect2, varscan2
- NADSYN1 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59812103; called by muse, mutect2, varscan2
- NAPEPLD | c.1134G>C p.L378F | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV58522182; called by muse, mutect2, varscan2
- NBPF3 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59058961; called by muse, varscan2
- NBPF3 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV59058974; called by muse, varscan2
- NCKAP5L | c.1922C>A p.S641* | Nonsense Mutation (SNP) | VAF 7/9 reads (78%) | catalogued as COSV100259191; called by muse, mutect2, varscan2
- NCSTN | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 60/381 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV54187496; called by muse, mutect2, varscan2
- NDUFS2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV63487809; called by muse, mutect2, varscan2
- NELL2 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV61574284; called by muse, mutect2, varscan2
- NFAT5 | c.4525C>A p.Q1509K | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV63027286; called by muse, mutect2, varscan2
- NFRKB | c.316A>T p.I106F (on ENST00000446488 / NM_001143835.2; = p.I119F on NM_006165.3) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV58757877; called by muse, mutect2, varscan2
- NHS | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 86/88 reads (98%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.811); catalogued as rs1389900417, COSV66274667; called by muse, mutect2, varscan2
- NKAPD1 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV54778234; called by muse, mutect2, varscan2
- NLGN1 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV64332816; called by muse, mutect2, varscan2
- NRDE2 | c.1506C>G p.F502L | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62963104, COSV62965015; called by muse, mutect2, varscan2
- NT5C1A | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs557786217, COSV52494161; called by muse, mutect2, varscan2
- NTNG1 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64271052; called by muse, mutect2, varscan2
- OGFRL1 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV64971909; called by muse, mutect2, varscan2
- OR10R2 | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 450/633 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759423191, COSV63768801, COSV63769462; called by muse, mutect2, varscan2
- OR2T10 | c.676C>G p.H226D | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.487); catalogued as COSV57896178, COSV57896781; called by muse, mutect2, varscan2
- OR51G2 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58992857, COSV58994038; called by muse, mutect2, varscan2
- OR52E6 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100259051, COSV61431511, COSV61432032; called by muse, mutect2
- OR5AS1 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1288571987, COSV57981730; called by muse, mutect2
- OR5M10 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV73242309; called by muse, mutect2, varscan2
- OR6F1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57467720, COSV57467735; called by muse, mutect2, varscan2
- OR8H3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs769797689, COSV57908525, COSV57908776; called by muse, mutect2, varscan2
- PAIP1 | c.572T>A p.V191D | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59085989; called by muse, mutect2, varscan2
- PAN2 | c.3060G>T p.E1020D (on ENST00000425394 / NM_001127460.3; = p.E1016D on NM_014871.5) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV56264315; called by muse, mutect2, varscan2
- PAX3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 103/110 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60588238; called by muse, mutect2, varscan2
- PCDH1 | c.2668A>G p.K890E | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54613725; called by muse, mutect2, varscan2
- PCDH11Y | c.2374G>T p.D792Y (on ENST00000400457 / NM_032973.2; = p.D781Y on NM_032971.3) | Missense Mutation (SNP) | VAF 70/109 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53080350; called by muse, mutect2, varscan2
- PCDH15 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 129/137 reads (94%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); catalogued as COSV57300174; called by muse, mutect2, varscan2
- PCDHA8 | c.782T>A p.V261D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV65336866; called by muse, mutect2, varscan2
- PCDHGA11 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs920128735, COSV53943718; called by muse, mutect2, varscan2
- PCDHGA8 | c.1931T>C p.V644A | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as rs755757019, COSV53943711; called by muse, mutect2, varscan2
- PCYT2 | c.316A>C p.N106H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV58711240; called by muse, mutect2, varscan2
- PDE11A | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327433951, COSV53693849; called by muse, mutect2, varscan2
- PDE3B | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56383391; called by muse, mutect2, varscan2
- PDE5A | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53348101; called by muse, mutect2, varscan2
- PDGFRA | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57267782, COSV99070921; called by muse, mutect2, varscan2
- PIGB | c.1396A>G p.K466E | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1037960754, COSV51241700; called by muse, mutect2, varscan2
- PIGO | c.2962G>C p.E988Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV53053595; called by muse, mutect2, varscan2
- PLIN4 | c.4012C>T p.Q1338* (on ENST00000301286; = p.Q1353* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 31/37 reads (84%) | catalogued as rs768971522; called by muse, mutect2, varscan2
- PLS3 | c.838C>G p.H280D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56778339; called by muse, mutect2, varscan2
- PNLIP | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as COSV65040424; called by muse, mutect2, varscan2
- PNLIPRP1 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 59/63 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62611730; called by muse, mutect2, varscan2
- POGLUT1 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55156459; called by muse, mutect2, varscan2
- POP1 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62892685; called by muse, varscan2
- PPM1F | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54284179; called by muse, mutect2, varscan2
- PRKD2 | c.2352C>G p.I784M | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52186618; called by muse, mutect2, varscan2
- PRSS57 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61385825; called by muse, mutect2, varscan2
- PRUNE1 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV54846893; called by muse, mutect2, varscan2
- PSMD1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV58078590; called by muse, mutect2, varscan2
- PTCHD1 | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65060004; called by muse, mutect2, varscan2
- PTK2B | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs1245860124, COSV57755968; called by muse, mutect2, varscan2
- PTP4A3 | c.415G>T p.G139* (on ENST00000329397; = p.G114* on NM_007079.3) | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100267394; called by muse, mutect2, varscan2
- PTPN22 | c.1423C>G p.Q475E (on ENST00000359785 / NM_001193431.2; = p.Q420E on NM_012411.5) | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63085010; called by muse, mutect2, varscan2
- PTPN4 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 78/136 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs781205857, COSV55301251; called by muse, mutect2, varscan2
- PTPRH | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV54745222; called by muse, mutect2, varscan2
- PYGO2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV63756944; called by muse, mutect2, varscan2
- RAI1 | c.1428T>G p.H476Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.25); catalogued as COSV55392668; called by muse, mutect2, varscan2
- RASAL1 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 418/698 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745498739, COSV55654744; called by muse, mutect2, varscan2
- RBM14 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs761053620, COSV59558872; called by muse, mutect2, varscan2
- RCOR1 | c.1357A>T p.S453C | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV51767927; called by muse, mutect2, varscan2
- RNF11 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54376399; called by muse, mutect2, varscan2
- RNF165 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1238181262, COSV53973454; called by muse, mutect2, varscan2
- RNF17 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV55040065; called by muse, mutect2, varscan2
- RNF39 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.737); catalogued as rs1353865256, COSV54993295; called by muse, mutect2, varscan2
- ROBO2 | c.1418T>C p.L473P | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59910213; called by muse, mutect2, varscan2
- ROBO2 | c.2328G>T p.K776N | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV59910226; called by muse, mutect2, varscan2
- ROCK2 | c.3676A>G p.R1226G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59956929; called by muse, mutect2, varscan2
- RUNX1T1 | c.824G>T p.R275L (on ENST00000265814 / NM_001198628.1; = p.R248L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV56140843, COSV56146054; called by muse, mutect2, varscan2
- RXRG | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV63232079; called by muse, mutect2, varscan2
- SBNO1 | c.3911A>T p.Y1304F (on ENST00000420886; = p.Y1303F on NM_018183.5) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV57341515; called by muse, mutect2, varscan2
- SCN1A | c.4028C>A p.A1343E (on ENST00000303395 / NM_001202435.3; = p.A1332E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57669294; called by muse, mutect2, varscan2
- SCN2A | c.4975G>C p.A1659P | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51840379; called by muse, mutect2, varscan2
- SEC16B | c.3035C>A p.S1012Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV57625433; called by muse, mutect2, varscan2
- SELENOI | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53144307, COSV99564308; called by muse, mutect2, varscan2
- SERPINB7 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV60533799; called by muse, mutect2, varscan2
- SHANK1 | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs1055212835, COSV53249798; called by mutect2, varscan2
- SLAMF6 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 64/679 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.617); catalogued as rs766194315, COSV63587049; called by muse, mutect2
- SLC20A1 | c.1982C>G p.S661C | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55611264; called by muse, mutect2, varscan2
- SLC2A3 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50001569, COSV50002019; called by muse, mutect2, varscan2
- SLC30A3 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.463); catalogued as rs375191770; called by muse, mutect2, varscan2
- SLC6A7 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as rs777422106, COSV57938259; called by muse, mutect2, varscan2
- SLC9A3 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.339); catalogued as rs147688367; called by muse, varscan2
- SLC9A5 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 74/78 reads (95%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV55361974; called by muse, mutect2, varscan2
- SLCO1A2 | c.1634C>A p.S545Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1482544260, COSV100262562, COSV56601632; called by muse, mutect2, varscan2
- SLCO1C1 | c.1382+1G>C p.X461_splice | Splice Site (SNP) | VAF 85/163 reads (52%) | catalogued as COSV56872244; called by muse, mutect2, varscan2
- SMARCD3 | c.453G>A p.M151I (on ENST00000262188 / NM_001003801.2; = p.M138I on NM_003078.4) | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV50390807; called by muse, mutect2, varscan2
- SNX19 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.322); catalogued as COSV56285568, COSV99773274; called by muse, mutect2, varscan2
- SOS2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV53567372; called by muse, mutect2, varscan2
- SPACA1 | c.732-1G>T p.X244_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV52759796; called by mutect2, varscan2
- SPEM2 | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61603864, COSV61603949; called by muse, mutect2, varscan2
- SPPL2C | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61292439; called by muse, mutect2, varscan2
- SPTLC3 | c.366C>G p.I122M | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV65465366; called by muse, mutect2, varscan2
- STAG1 | c.2546-1G>C p.X849_splice | Splice Site (SNP) | VAF 29/184 reads (16%) | catalogued as COSV52608856; called by muse, mutect2, varscan2
- STAG1 | c.967A>T p.S323C | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV52608865; called by muse, mutect2, varscan2
- STK32B | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51485546; called by muse, mutect2, varscan2
- STRAP | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV50308512; called by muse, mutect2, varscan2
- SULT1A1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV59087922; called by muse, mutect2, varscan2
- SYNPO | c.2461A>C p.I821L (on ENST00000394243 / NM_001166208.2; = p.I577L on NM_007286.6) | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV56940027; called by muse, mutect2, varscan2
- SYNPO2 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV61110532; called by muse, mutect2, varscan2
- TARS2 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60872951; called by muse, mutect2, varscan2
- TBC1D7 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58243992; called by mutect2, varscan2
- TBCD | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62800704; called by muse, mutect2, varscan2
- TBXT | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs747724104, COSV51617805, COSV99752055; called by muse, mutect2, varscan2
- TECR | c.15G>A p.E5= | Splice Region (SNP) | VAF 8/58 reads (14%) | catalogued as COSV53110600; called by muse, mutect2, varscan2
- THAP12 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52610403; called by muse, mutect2, varscan2
- THRAP3 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 94/104 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV57176500; called by muse, mutect2, varscan2
- TIAM1 | c.1465A>T p.S489C | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV54550027; called by muse, mutect2, varscan2
- TLE1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as COSV64690315; called by muse, mutect2, varscan2
- TLE3 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV58169222; called by muse, mutect2, varscan2
- TMEM144 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs758212029, COSV56700749; called by muse, mutect2, varscan2
- TMEM260 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55098973; called by muse, mutect2, varscan2
- TMIE | c.379A>C p.K127Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.744); catalogued as COSV58405687; called by muse, mutect2, varscan2
- TMTC4 | c.313G>T p.V105L (on ENST00000376234 / NM_001350577.2; = p.V124L on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs377347768, COSV60893423; called by muse, mutect2, varscan2
- TNS3 | c.1394A>T p.N465I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60790716; called by muse, mutect2, varscan2
- TOGARAM1 | c.3813-1G>C p.X1271_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100818243; called by mutect2, varscan2
- TP53BP1 | c.4544A>C p.Y1515S | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55500859; called by muse, mutect2
- TPGS2 | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs925813121, COSV57540471; called by muse, mutect2, varscan2
- TRAF3IP3 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV50552607; called by muse, mutect2, varscan2
- TRMT10A | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV56744983; called by muse, mutect2, varscan2
- TRPA1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 144/405 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51561121; called by muse, mutect2, varscan2
- TRPV1 | c.1968C>G p.F656L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as COSV51518200; called by muse, mutect2, varscan2
- TSHZ2 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 116/175 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61588659, COSV61589419; called by muse, mutect2, varscan2
- TTC7B | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV60630690; called by muse, mutect2
- TTN | c.100376C>T p.A33459V (on ENST00000591111; = p.A26035V on NM_003319.4) | Missense Mutation (SNP) | VAF 37/49 reads (76%) | PolyPhen benign (0.003); catalogued as COSV60042221; called by muse, mutect2, varscan2
- TTN | c.77860A>T p.I25954F (on ENST00000591111; = p.I18530F on NM_003319.4) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | PolyPhen possibly damaging (0.463); catalogued as COSV60042262; called by muse, mutect2, varscan2
- TTN | c.74567T>C p.V24856A (on ENST00000591111; = p.V17432A on NM_003319.4) | Missense Mutation (SNP) | VAF 73/303 reads (24%) | PolyPhen benign (0.005); catalogued as COSV60042307; called by muse, mutect2, varscan2
- TTN | c.65777A>G p.Y21926C (on ENST00000591111; = p.Y14502C on NM_003319.4) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | PolyPhen probably damaging (1); catalogued as rs1004548694, COSV60042345; called by muse, mutect2, varscan2
- TUBB4A | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 161/207 reads (78%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV51154834; called by muse, mutect2, varscan2
- TXNDC11 | c.927A>T p.K309N (on ENST00000356957 / NM_001303447.2; = p.K282N on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV51598958; called by muse, mutect2, varscan2
- UBE2A | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 89/93 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60636569; called by muse, mutect2, varscan2
- UFL1 | c.2083C>A p.Q695K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65149826, COSV65149880; called by muse, mutect2, varscan2
- UNC13C | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52870015, COSV52877408; called by muse, mutect2, varscan2
- USF3 | c.3595C>T p.Q1199* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV57071474; called by muse, mutect2, varscan2
- USP28 | c.1260_1261del p.K420Nfs*30 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs747536324; called by mutect2, pindel, varscan2
- USP37 | c.2575G>C p.G859R | Missense Mutation (SNP) | VAF 82/86 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51443223; called by muse, mutect2, varscan2
- VIPR2 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51106518; called by muse, mutect2, varscan2
- VN1R4 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV100237289, COSV60804956; called by muse, mutect2, varscan2
- VSIG10 | c.1166G>C p.R389P | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63653267, COSV63654230; called by muse, mutect2, varscan2
- VWCE | c.2845C>T p.R949W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs199724001, COSV57111745; called by muse, mutect2, varscan2
- WDR17 | c.3107G>A p.R1036K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV54573607; called by muse, mutect2, varscan2
- WDR20 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as rs1415856448, COSV54472070; called by muse, mutect2, varscan2
- ZBED1 | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV58133368; called by muse, mutect2, varscan2
- ZBTB20 | c.458A>G p.K153R (on ENST00000474710 / NM_001164342.2; = p.K80R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV61849802; called by muse, mutect2, varscan2
- ZFHX4 | c.6499G>T p.G2167C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV50766550; called by muse, mutect2, varscan2
- ZFP14 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV54202308; called by muse, mutect2, varscan2
- ZFYVE26 | c.2223G>C p.K741N | Missense Mutation (SNP) | VAF 103/147 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV61328147; called by muse, mutect2, varscan2
- ZIC2 | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774529965, COSV66254950; called by muse, mutect2, varscan2
- ZNF334 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV61618606; called by muse, mutect2, varscan2
- ZNF354A | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV59983178; called by muse, mutect2, varscan2
- ZNF394 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV58742383; called by muse, mutect2, varscan2
- ZNF507 | c.1863C>G p.S621R | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as COSV61331218, COSV61333428; called by muse, mutect2
- ZNF528 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV64619298; called by muse, mutect2, varscan2
- ZNF558 | c.605A>C p.H202P | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56863116; called by muse, mutect2, varscan2
- ZNF641 | c.319-2A>T p.X107_splice | Splice Site (SNP) | VAF 45/89 reads (51%) | catalogued as COSV56390176; called by muse, mutect2, varscan2
- ZNF644 | c.2547G>C p.K849N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV61347686, COSV61347696; called by muse, mutect2, varscan2
- ZNF713 | c.454G>A p.G152R (on ENST00000633730 / NM_001366796.2; = p.G165R on NM_182633.3) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70056684; called by muse, mutect2, varscan2
- ZSWIM1 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54847347; called by muse, mutect2, varscan2
- ZZEF1 | c.8129A>G p.N2710S | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV67556023; called by muse, mutect2, varscan2
- ADAM29 | c.1352C>G p.S451* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- ATG2A | c.1084_1085del p.T362* | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by pindel, varscan2
- BAZ1A | c.3263_3264del p.E1088Afs*4 | Frame Shift Del (DEL) | VAF 36/189 reads (19%) | called by pindel, varscan2
- CADM3 | c.787C>T p.Q263* (on ENST00000368125 / NM_001127173.3; = p.Q297* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 119/159 reads (75%) | called by muse, mutect2, varscan2
- CD200 | c.135G>A p.W45* (on ENST00000473539 / NM_001004196.3; = p.W20* on NM_005944.7 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2
- CREB5 | c.660T>A p.C220* (on ENST00000357727 / NM_182898.4; = p.C213* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- CSPG4 | c.1956del p.T653Rfs*2 | Frame Shift Del (DEL) | VAF 46/86 reads (53%) | called by mutect2, pindel, varscan2
- DENND1C | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FAT1 | c.5792_5799del p.Y1931Wfs*20 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by pindel, varscan2
- FKBP5 | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 64/70 reads (91%) | called by muse, mutect2, varscan2
- ID1 | c.78C>G p.S26R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.148); called by muse, mutect2
- KAT2A | c.1575dup p.V526Cfs*11 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- MACF1 | c.8536G>T p.E2846* | Nonsense Mutation (SNP) | VAF 18/21 reads (86%) | called by muse, mutect2, varscan2
- MKI67 | c.1447_1479del p.S483_I493del | In Frame Del (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel
- NELL1 | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- OR6F1 | c.644_645del p.F215Cfs*79 | Frame Shift Del (DEL) | VAF 109/224 reads (49%) | called by mutect2, pindel, varscan2
- OR8B8 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- PAQR5 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 68/251 reads (27%) | called by muse, mutect2, varscan2
- PDE9A | c.204dup p.A69Rfs*35 | Frame Shift Ins (INS) | VAF 28/54 reads (52%) | called by pindel, varscan2
- PHLPP1 | c.1900-5_1912del p.X634_splice | Splice Site (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel
- PPP1R16A | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PRKCSH | c.1009-1G>A p.X337_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- RBL2 | c.1319_1340del p.P440Lfs*17 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- RIF1 | c.7202C>G p.S2401* | Nonsense Mutation (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- RRAGB | c.682G>T p.E228* (on ENST00000262850 / NM_016656.4; = p.E200* on NM_006064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- SFSWAP | c.1672A>T p.K558* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- SLC1A1 | c.484-15_494del p.X162_splice | Splice Site (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel
- TENM1 | c.6264_6290del p.N2088_M2096del | In Frame Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- TRDN | c.115_116del p.D39Hfs*30 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- ZNF260 | c.270del p.A91Pfs*233 | Frame Shift Del (DEL) | VAF 28/43 reads (65%) | called by mutect2, pindel, varscan2
- ABCA13 | c.6828A>G p.L2276= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV70028293; called by muse, mutect2, varscan2
- ABTB1 | c.48C>T p.G16= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV51741181; called by muse, mutect2, varscan2
- ACACA | c.6768G>C p.L2256= | Silent (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- ADCY4 | c.858C>T p.A286= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV53475304; called by muse, mutect2, varscan2
- ADGRL3 | c.2199G>T p.A733= (on ENST00000506720 / NM_001322402.2; = p.A665= on NM_015236.6) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs199658315, COSV101547183, COSV72230506; called by muse, mutect2, varscan2
- AHNAK | c.9339G>T p.L3113= | Silent (SNP) | VAF 109/256 reads (43%) | catalogued as COSV57212759; called by muse, mutect2, varscan2
- AKAP17A | c.1326G>T p.L442= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1415696774, COSV58309534; called by muse, mutect2, varscan2
- AMOTL1 | c.2202C>T p.I734= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as COSV58566467; called by muse, mutect2, varscan2
- ANKS1B | c.1203A>T p.P401= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV61350012; called by muse, mutect2, varscan2
- ARID1B | c.1824G>T p.P608= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV51660803; called by muse, mutect2, varscan2
- ATM | c.5619T>C p.C1873= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV53742927; called by muse, mutect2
- ATP2B3 | c.642G>A p.G214= | Silent (SNP) | VAF 73/82 reads (89%) | catalogued as rs782656923, COSV54846608, COSV99685736; called by muse, mutect2, varscan2
- BARHL1 | c.414A>G p.R138= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as COSV55037620; called by muse, mutect2, varscan2
- BEND7 | c.1212C>T p.L404= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs763540443, COSV100346555, COSV61988901; called by muse, mutect2, varscan2
- C2CD5 | c.1315A>C p.R439= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV61724442; called by muse, mutect2, varscan2
- C7orf57 | c.135C>T p.S45= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs746538863, COSV62362690; called by muse, mutect2, varscan2
- CACNA1A | c.5820C>A p.S1940= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV64197322, COSV64198668; called by muse, mutect2, varscan2
- CD19 | c.957G>C p.L319= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs1194984692, COSV61188521; called by muse, mutect2, varscan2
- CDKN2AIP | c.1108C>T p.L370= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs753652052, COSV56627165; called by muse, mutect2, varscan2
- CEP250 | c.858C>G p.T286= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV61168480, COSV61169935; called by muse, mutect2, varscan2
- CHRM3 | c.1452C>G p.V484= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV55088381; called by muse, varscan2
- CIT | c.2556G>A p.L852= | Silent (SNP) | VAF 238/640 reads (37%) | catalogued as COSV55867978; called by muse, mutect2, varscan2
- CNGA3 | c.222G>A p.S74= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs775081515, COSV55623862, COSV99736151; called by muse, mutect2, varscan2
- CNKSR3 | c.1461C>T p.P487= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs767855966, COSV70481021; called by muse, mutect2, varscan2
- CNR1 | c.408G>T p.L136= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV62987202; called by muse, mutect2, varscan2
- COL5A1 | c.2769C>G p.P923= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV65668743; called by muse, mutect2, varscan2
- CRP | c.612C>T p.N204= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs765921487, COSV54812919; called by muse, mutect2, varscan2
- CSMD3 | c.9321A>G p.P3107= (on ENST00000297405 / NM_001363185.1; = p.P2938= on NM_052900.3) | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as rs1434936840, COSV52173714; called by muse, mutect2
- CTTN | c.1212G>C p.V404= | Silent (SNP) | VAF 91/199 reads (46%) | catalogued as COSV57232150; called by muse, mutect2, varscan2
- CYP24A1 | c.510G>T p.G170= | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as COSV53774036; called by muse, mutect2, varscan2
- DNAH10 | c.11182C>T p.L3728= (on ENST00000409039; = p.L3667= on NM_207437.3) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV68993346; called by muse, mutect2, varscan2
- DNAH11 | c.9606C>T p.L3202= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV60954822; called by muse, mutect2, varscan2
- DNAH12 | c.381A>G p.L127= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV60856907; called by muse, mutect2, varscan2
- DNAH17 | c.2145C>T p.G715= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV67753959; called by muse, mutect2, varscan2
- DNAH5 | c.10624C>T p.L3542= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV54223333; called by muse, mutect2, varscan2
- DNAJB7 | c.222C>T p.N74= | Silent (SNP) | VAF 75/76 reads (99%) | catalogued as rs571921787, COSV53421778; called by muse, mutect2, varscan2
- EXT2 | c.1917G>T p.T639= (on ENST00000343631; = p.T672= on NM_000401.3) | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV59149801, COSV59151870; called by muse, mutect2, varscan2
- EYA4 | c.267T>A p.S89= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as COSV62046037; called by muse, mutect2, varscan2
- FCGBP | c.12426G>A p.K4142= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as rs748922105; called by muse, mutect2, varscan2
- FKBP15 | c.3438A>T p.T1146= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1320512302, COSV53034473; called by muse, mutect2, varscan2
- FOXG1 | c.1395G>A p.T465= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as rs369183477, COSV57394845; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMPD1 | c.3522A>T p.P1174= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV66700303; called by muse, mutect2, varscan2
- GCA | c.384C>T p.F128= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV52025485; called by muse, mutect2, varscan2
- GIGYF1 | c.2280C>G p.L760= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs911032111, COSV51941602; called by muse, mutect2, varscan2
- GLI2 | c.3690T>C p.Y1230= (on ENST00000361492 / NM_001374353.1; = p.Y1247= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as COSV58041474; called by muse, mutect2, varscan2
- GLTP | c.546C>G p.L182= | Silent (SNP) | VAF 172/424 reads (41%) | catalogued as COSV59172801; called by muse, mutect2, varscan2
- GNA14 | c.621G>A p.S207= | Silent (SNP) | VAF 142/236 reads (60%) | catalogued as rs371304229; called by muse, mutect2, varscan2
- GOLGB1 | c.7251G>A p.L2417= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV61465618; called by muse, mutect2, varscan2
- GOLT1A | c.156G>A p.L52= | Silent (SNP) | VAF 76/105 reads (72%) | catalogued as COSV57643747; called by muse, mutect2, varscan2
- GRK7 | c.162G>A p.L54= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as COSV53822773; called by muse, mutect2, varscan2
- GRM4 | c.2397G>T p.L799= | Silent (SNP) | VAF 62/65 reads (95%) | catalogued as COSV65213141; called by muse, mutect2, varscan2
- GRM5 | c.465C>A p.A155= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV59603941; called by muse, mutect2, varscan2
- GSAP | c.1935T>C p.I645= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as COSV57529848; called by muse, mutect2
- GSDME | c.618C>T p.N206= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs142033677; called by muse, mutect2, varscan2
- HDAC7 | c.315C>G p.V105= (on ENST00000427332; = p.V144= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 236/514 reads (46%) | catalogued as COSV50348042, COSV50408770; called by muse, mutect2, varscan2
- HGFAC | c.1410G>A p.T470= | Silent (SNP) | VAF 273/432 reads (63%) | catalogued as rs774866644, COSV66976856; called by muse, mutect2, varscan2
- HIPK3 | c.2607C>T p.V869= | Silent (SNP) | VAF 68/171 reads (40%) | catalogued as rs775139853, COSV57562398; called by muse, mutect2, varscan2
- HSPA12B | c.1020C>T p.L340= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV53923863; called by muse, mutect2, varscan2
- HSPE1 | c.308G>A p.*103= | Silent (SNP) | VAF 49/60 reads (82%) | called by muse, mutect2, varscan2
- IGHG1 | c.828C>A p.T276= | Silent (SNP) | VAF 159/301 reads (53%) | called by muse, mutect2, varscan2
- IGHG3 | c.204G>C p.V68= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- IKZF1 | c.1404G>T p.R468= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV58785501; called by muse, mutect2, varscan2
- IL4I1 | c.807G>T p.L269= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as COSV55578467; called by muse, mutect2, varscan2
- KCNK9 | c.190C>T p.L64= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV57281281; called by muse, mutect2, varscan2
- KIF27 | c.1291C>T p.L431= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52827548; called by muse, mutect2, varscan2
- KRTAP10-4 | c.612C>T p.C204= | Silent (SNP) | VAF 104/120 reads (87%) | catalogued as COSV59961355; called by muse, mutect2, varscan2
- LAG3 | c.129C>A p.P43= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV52567425; called by muse, mutect2, varscan2
- LDHC | c.30G>A p.E10= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV55004221, COSV55006137; called by muse, mutect2, varscan2
- LILRA4 | c.774G>A p.E258= | Silent (SNP) | VAF 39/40 reads (98%) | catalogued as COSV52492174; called by muse, mutect2, varscan2
- LRRTM4 | c.1470T>A p.P490= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV69139989; called by muse, mutect2, varscan2
- LRRTM4 | c.729C>T p.S243= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV69139993; called by muse, mutect2, varscan2
- MAPK10 | c.81G>A p.Q27= (on ENST00000359221 / NM_001351625.2; = p.Q65= on NM_002753.5) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV60381693; called by muse, mutect2, varscan2
- MAST1 | c.3339G>T p.S1113= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV52246433; called by muse, mutect2, varscan2
- MFSD4A | c.1242C>T p.L414= | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV65656426; called by muse, mutect2, varscan2
- MINDY4 | c.987C>G p.L329= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV54673668; called by muse, mutect2, varscan2
- MINK1 | c.2586C>T p.S862= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs756350885, COSV53417916; called by muse, mutect2, varscan2
- MTCL1 | c.2073G>T p.G691= (on ENST00000306329 / NM_001378206.1; = p.G331= on NM_015210.4) | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as COSV60405883; called by muse, mutect2, varscan2
- MTERF1 | c.333T>A p.L111= | Silent (SNP) | VAF 116/164 reads (71%) | catalogued as COSV61098237; called by muse, mutect2, varscan2
- MUC16 | c.4944C>A p.A1648= | Silent (SNP) | VAF 136/175 reads (78%) | catalogued as COSV67464214; called by muse, mutect2, varscan2
- NCBP1 | c.2367G>A p.Q789= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV64305171; called by muse, mutect2, varscan2
- NES | c.3750G>A p.Q1250= | Silent (SNP) | VAF 66/352 reads (19%) | catalogued as COSV63960978; called by muse, mutect2, varscan2
- NOS1 | c.1188T>C p.T396= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV57611881; called by muse, mutect2, varscan2
- NPR2 | c.240A>G p.A80= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as COSV61310560; called by muse, mutect2, varscan2
- NPTX2 | c.1044C>T p.G348= | Silent (SNP) | VAF 63/78 reads (81%) | catalogued as rs756266964, COSV55717138; called by muse, mutect2, varscan2
- NUP210L | c.4095C>T p.V1365= | Silent (SNP) | VAF 131/194 reads (68%) | catalogued as COSV55147106; called by muse, mutect2, varscan2
- NUTM1 | c.540A>G p.P180= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV61546988; called by muse, mutect2, varscan2
- OPHN1 | c.654A>G p.T218= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as COSV62782173; called by muse, mutect2, varscan2
- OR1A2 | c.174C>T p.P58= | Silent (SNP) | VAF 147/367 reads (40%) | catalogued as COSV67936391; called by muse, mutect2, varscan2
- OR5R1 | c.684C>T p.I228= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV56571885, COSV56572238; called by muse, mutect2, varscan2
- OR6N2 | c.159A>G p.A53= | Silent (SNP) | VAF 211/286 reads (74%) | catalogued as COSV59411282; called by muse, mutect2, varscan2
- PAQR9 | c.195T>A p.R65= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV61418118; called by muse, mutect2, varscan2
- PCDHA12 | c.150G>A p.Q50= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV56499046; called by muse, mutect2, varscan2
- PDCD4 | c.960G>C p.G320= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV54522776; called by muse, mutect2, varscan2
- PDILT | c.1077C>T p.L359= | Silent (SNP) | VAF 63/100 reads (63%) | catalogued as COSV56701747, COSV56701789; called by muse, mutect2, varscan2
- PKHD1L1 | c.996C>G p.L332= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV65742624; called by muse, mutect2, varscan2
- PLD1 | c.924A>G p.L308= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV60567838; called by muse, mutect2, varscan2
- POM121L12 | c.318C>G p.T106= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV68692898; called by muse, mutect2, varscan2
- POTEF | c.574C>T p.L192= | Silent (SNP) | VAF 47/268 reads (18%) | catalogued as COSV62541132; called by muse, varscan2
- POU6F2 | c.441C>A p.T147= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs751554807, COSV68873195, COSV68874385; called by muse, mutect2, varscan2
- PRKDC | c.11448T>C p.L3816= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV58051445; called by muse, mutect2, varscan2
- PTAR1 | c.1074G>T p.R358= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV61208470; called by muse, mutect2, varscan2
- RABGGTA | c.579C>T p.P193= | Silent (SNP) | VAF 50/256 reads (20%) | catalogued as rs1276686580, COSV53770219; called by muse, mutect2, varscan2
- RASGEF1B | c.1110G>A p.V370= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV52337029; called by muse, mutect2, varscan2
- RGS12 | c.3000G>A p.A1000= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs139780010; called by muse, mutect2, varscan2
- RPL35 | c.72G>A p.L24= | Silent (SNP) | VAF 49/60 reads (82%) | catalogued as rs760779000, COSV62018973; called by muse, mutect2, varscan2
- RSPH3 | c.843G>A p.L281= (on ENST00000252655; = p.L139= on NM_031924.8) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV51922572; called by muse, mutect2, varscan2
- SCN2A | c.5832C>A p.P1944= | Silent (SNP) | VAF 43/59 reads (73%) | catalogued as COSV51840403; called by muse, mutect2, varscan2
- SGPP1 | c.1104G>T p.R368= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV55975351; called by muse, mutect2, varscan2
- SLC18A3 | c.1482C>T p.Y494= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV60324699; called by muse, mutect2, varscan2
- SLCO5A1 | c.786C>A p.V262= | Silent (SNP) | VAF 47/67 reads (70%) | catalogued as COSV52659012; called by muse, mutect2, varscan2
- SMTNL1 | c.1059C>A p.A353= (on ENST00000399154; = p.A390= on NM_001105565.2) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV67699753; called by muse, mutect2, varscan2
- SMYD1 | c.1098C>A p.A366= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV70224389; called by muse, mutect2, varscan2
- SPATA5L1 | c.2158C>T p.L720= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV59744575; called by muse, mutect2, varscan2
- SPICE1 | c.618C>G p.L206= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV55620377; called by muse, mutect2, varscan2
- SYT3 | c.102G>A p.Q34= | Silent (SNP) | VAF 159/163 reads (98%) | catalogued as COSV58896441; called by muse, mutect2, varscan2
- TIAM1 | c.1464C>T p.N488= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as rs767333120, COSV54550049; called by muse, mutect2, varscan2
- TMEM229B | c.109T>C p.L37= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV62538688; called by muse, mutect2, varscan2
- TOPORS | c.456G>A p.V152= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV62116870; called by muse, mutect2, varscan2
- TRIOBP | c.1476C>G p.P492= | Silent (SNP) | VAF 74/186 reads (40%) | catalogued as COSV60377066; called by muse, varscan2
- TSPAN14 | c.342G>A p.L114= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs767571263, COSV59368013; called by muse, mutect2, varscan2
- TSPO2 | c.139T>C p.L47= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as rs770525048, COSV55109902; called by muse, mutect2, varscan2
- TTPAL | c.741A>T p.I247= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- UBA3 | c.465C>T p.F155= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV62740404; called by muse, mutect2, varscan2
- USP34 | c.10005G>A p.E3335= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV63724974; called by muse, mutect2, varscan2
- VAT1L | c.618C>T p.N206= | Silent (SNP) | VAF 65/70 reads (93%) | catalogued as rs147711332; called by muse, mutect2, varscan2
- XAF1 | c.651A>T p.I217= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV60971869; called by muse, mutect2, varscan2
- ZMAT1 | c.297T>A p.G99= | Silent (SNP) | VAF 28/28 reads (100%) | catalogued as COSV65658480; called by muse, mutect2, varscan2
- ZNF236 | c.408G>A p.L136= | Silent (SNP) | VAF 92/174 reads (53%) | catalogued as COSV53487787; called by muse, mutect2, varscan2
- ZNF512 | c.252G>A p.K84= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV62675418; called by muse, mutect2, varscan2
- ZNF646 | c.3249C>T p.V1083= | Silent (SNP) | VAF 173/540 reads (32%) | catalogued as COSV54924175; called by muse, mutect2, varscan2
- EIF4A2 | c.771+104G>A | Intron (SNP) | VAF 34/69 reads (49%) | catalogued as COSV99961354; called by muse, mutect2, varscan2
- ELP4 | c.1147-19962G>C | Intron (SNP) | VAF 15/30 reads (50%) | catalogued as COSV63352360; called by muse, mutect2, varscan2
- GLRX2 | chr1:193105617 C>T | 5'Flank (SNP) | VAF 4/27 reads (15%) | catalogued as COSV66471893; called by muse, mutect2, varscan2
- KDELR2 | c.*105C>G | 3'UTR (SNP) | VAF 31/36 reads (86%) | catalogued as COSV51726426, COSV99330558; called by muse, mutect2, varscan2
- LRRC61 | c.-1C>T | 5'UTR (SNP) | VAF 71/133 reads (53%) | catalogued as rs1248312027, COSV99784542; called by muse, mutect2, varscan2
- MXD3 | c.*2G>C | 3'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57463280; called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610089 C>A | 5'Flank (SNP) | VAF 48/161 reads (30%) | catalogued as rs765534937; called by muse, mutect2, varscan2
- OR8A1 | c.-13C>T | 5'UTR (SNP) | VAF 17/32 reads (53%) | catalogued as COSV52508573, COSV99420517; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1292A>T | RNA (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- SEPTIN8 | c.1286+2290G>T | Intron (SNP) | VAF 12/20 reads (60%) | catalogued as COSV99736587, COSV99736664; called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4448C>G | Intron (SNP) | VAF 22/145 reads (15%) | catalogued as COSV50252453; called by muse, mutect2, varscan2
- SVIL | c.827+5536A>T | Intron (SNP) | VAF 29/132 reads (22%) | catalogued as COSV100881510; called by muse, mutect2, varscan2
- TTN | c.10303+2528G>A | Intron (SNP) | VAF 25/34 reads (74%) | catalogued as rs752146394, COSV100618080, COSV60042385; called by muse, mutect2, varscan2
